Gene-level copy-number profile of tumor specimen TCGA-CQ-A4CB-01A from TCGA case TCGA-CQ-A4CB, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 59.1 years (21,574 days).
Specimen TCGA-CQ-A4CB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.3268ba5f-22e5-4e36-943e-72b2f90698bb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CQ-A4CB-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/45f1ca89-35e6-4253-9bea-ebebf1dc4e45

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 73; copy number 1: 41; copy number 2: 10,289; copy number 3: 764; copy number 4: 45,208; copy number 5: 220; copy number 6: 1,660; copy number 7: 705; copy number 9: 260; copy number 10: 222; copy number 11: 106; copy number 12: 210; copy number 19: 4; copy number 32: 44; copy number 41: 3; copy number 48: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CQ-A4CB-01A-11D-A253-01): tumor purity 0.37, ploidy 1.93, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 73 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,745–846,561, 11 genes (within-gene range 0–5): LINC01986, AC066595.1, CHL1-AS2, AC066595.2, CHL1, RNU6-1194P, RPS8P6, CHL1-AS1, AC087428.1, LINC01266, RPSAP32.
- chr3:11,137,093–11,771,350, 10 genes (within-gene range 0–3): HRH1, AC083855.2, CHCHD4P4, ATG7, AC083855.1, AC026185.1, AC022001.1, VGLL4, AC022001.2, AC022001.3.
- chr3:27,110,085–31,637,616, 46 genes: NEK10, MICOS10P3, RNU6-342P, AC099535.2, SLC4A7, RPS20P15, AC099535.1, RNU1-96P, AC137675.1, Y_RNA, AC098614.1, AC098614.2, KIAA1143P2, LINC02084, EOMES, LINC01980, LINC01981, LINC01967, CMC1, AZI2, ZCWPW2, AC098650.1, FAM96AP1, AC093142.1, RBMS3, RBMS3-AS3, MESTP4, RPS12P5, RBMS3-AS2, MTND4LP9, RBMS3-AS1, AC025614.2, AC025614.1, U3, LINC01985, AC116035.1, TGFBR2, AC096921.1, AC096921.2, GADL1, MIR466, CNN2P6, RNA5SP127, H3P11, THRAP3P1, STT3B.
- chr3:31,704,058–31,721,652, 1 gene: OSBPL10-AS1.
- chr18:80,109,262–80,247,514, 5 genes (within-gene range 0–3): ADNP2, PARD6G-AS1, PARD6G, AC139100.2, AC139100.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 854 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:105,366,909–106,427,977, 5 genes, copy number 11: ALCAM, CBLB, AC131237.1, AC079382.1, AC079382.2.
- chr3:106,515,897–106,515,998, 1 gene, copy number 11: Y_RNA.
- chr3:109,241,507–109,810,861, 12 genes, copy number 19–48 (within-gene range 17–48): AC063923.1, DPPA2, Metazoa_SRP, DPPA4, AC124945.1, AC092905.1, H3P12, LINC01205, PPIAP15, MIR4445, AC078980.1, DIMT1P1.
- chr3:182,691,928–190,892,429, 181 genes, copy number 12 (broad region; genes not listed).
- chr3:195,701,618–198,222,513, 100 genes, copy number 11 (within-gene range 7–11) (broad region; genes not listed).
- chr5:37,939,365–38,184,717, 4 genes, copy number 9 (within-gene range 4–9): AC008869.1, LINC02110, AC034226.1, LINC02119.
- chr5:50,396,192–67,902,600, 256 genes, copy number 9 (broad region; genes not listed).
- chr11:64,486,136–67,653,404, 222 genes, copy number 10 (broad region; genes not listed).
- chr11:69,147,228–71,818,238, 73 genes, copy number 12–32 (within-gene range 6–32) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 41. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
